Somatic mutation profile of tumor specimen C3L-02610-01 (aliquot CPT0124980007) from CPTAC case C3L-02610, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 80.9 years (29,536 days).
Specimen C3L-02610-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8baacda2-05d9-4fd5-afb1-1d1fe75e7140.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02610-31 (Blood Derived Normal), aliquot CPT0125020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68739039-08a7-405a-93e1-cba235a49e0a

The open-access MAF lists 53 somatic variants for this specimen: 31 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 17, 3'Flank 1, Intron 1, Splice Site 1, Frame Shift Del 1, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 67/257 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 56/368 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as CM056067, CM920671, CM942120, COSV52675795, COSV52676870, COSV52730435, COSV53567603; called by muse, mutect2, varscan2
- CDKN2A | c.47_50del p.L16Pfs*9 | Frame Shift Del (DEL) | VAF 32/219 reads (15%) | catalogued as rs587782206; called by pindel, varscan2
- CNTN6 | c.2398G>T p.D800Y | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63192865; called by muse, mutect2
- COLEC11 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 56/658 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.519); catalogued as COSV99363298; called by muse, mutect2
- CSMD1 | c.548T>A p.L183Q | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460363308, COSV101213984; called by muse, mutect2, varscan2
- DCLK1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1566022803, COSV55191105; called by muse, mutect2
- FAM240A | c.55C>T p.R19C (on ENST00000444264; = p.R13C on NM_001195442.2) | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs766427639; called by muse, mutect2, varscan2
- GIMAP8 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs749652932, COSV56230970; called by muse, mutect2, varscan2
- IL21R | c.432C>A p.D144E | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs949248876; called by muse, mutect2, varscan2
- MKRN3 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs779114986, COSV58809720; called by muse, mutect2
- MPP7 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200656300; called by muse, mutect2, varscan2
- PDZRN4 | c.3052G>A p.A1018T (on ENST00000402685 / NM_001164595.2; = p.A760T on NM_013377.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.031); catalogued as COSV100114636; called by muse, mutect2
- RNF43 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs748533737, COSV68458461; called by muse, mutect2, varscan2
- SMAD4 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 50/282 reads (18%) | catalogued as COSV61686461, COSV61695955; called by muse, mutect2, varscan2
- SMOC1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs376548937; called by muse, mutect2, varscan2
- TMEM121 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs960108232; called by muse, mutect2, varscan2
- ZNF610 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs768546961; called by muse, mutect2, varscan2
- ARVCF | c.2645G>A p.G882D | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.06); called by muse, mutect2
- CDT1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CRACD | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 40/325 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- GML | c.73+2T>C p.X25_splice | Splice Site (SNP) | VAF 18/196 reads (9%) | called by muse, mutect2
- GNAI2 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); called by muse, mutect2
- GSG1L | c.245dup p.G83Wfs*36 | Frame Shift Ins (INS) | VAF 13/132 reads (10%) | called by mutect2, pindel
- LAMA4 | c.5182G>T p.D1728Y (on ENST00000230538 / NM_001105206.3; = p.D1721Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/375 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTERF1 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- MUC17 | c.935C>G p.A312G | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2
- PDS5B | c.4090A>C p.I1364L | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- POSTN | c.2302G>A p.G768R | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- STARD9 | c.12895C>A p.L4299I | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- TRIM35 | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ADAM19 | c.2490G>A p.S830= | Silent (SNP) | VAF 22/162 reads (14%) | catalogued as rs764968777, COSV57427459; called by muse, mutect2, varscan2
- C22orf31 | c.606G>A p.T202= | Silent (SNP) | VAF 36/277 reads (13%) | catalogued as rs776057378, COSV53310737; called by muse, mutect2, varscan2
- CCDC30 | c.2352T>C p.S784= (on ENST00000340612; = p.S741= on NM_001080850.3) | Silent (SNP) | VAF 23/244 reads (9%) | catalogued as rs765865782; called by muse, mutect2, varscan2
- CCT6B | c.117T>C p.G39= | Silent (SNP) | VAF 13/83 reads (16%) | called by mutect2, varscan2
- CECR2 | c.3387G>A p.T1129= (on ENST00000342247 / NM_001290047.2; = p.T945= on NM_001290046.1) | Silent (SNP) | VAF 36/274 reads (13%) | catalogued as rs751868810; called by muse, mutect2, varscan2
- DMXL1 | c.8157C>T p.G2719= | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as rs751162158; called by muse, mutect2, varscan2
- ERGIC3 | c.744C>T p.H248= | Silent (SNP) | VAF 23/218 reads (11%) | called by muse, mutect2, varscan2
- F10 | c.1215C>T p.A405= | Silent (SNP) | VAF 52/538 reads (10%) | catalogued as rs770904651; ClinVar: uncertain significance; called by muse, mutect2
- FOXH1 | c.445C>T p.L149= | Silent (SNP) | VAF 73/332 reads (22%) | called by muse, mutect2, varscan2
- FZD9 | c.678C>A p.R226= | Silent (SNP) | VAF 43/187 reads (23%) | called by muse, mutect2, varscan2
- INPPL1 | c.1608C>T p.N536= | Silent (SNP) | VAF 27/209 reads (13%) | called by muse, mutect2, varscan2
- OR4K2 | c.264T>C p.G88= | Silent (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
- OR51V1 | c.819C>T p.P273= | Silent (SNP) | VAF 22/191 reads (12%) | catalogued as rs142226521; called by muse, mutect2, varscan2
- PDZRN3 | c.714C>T p.P238= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs576789805; called by muse, mutect2, varscan2
- SLC2A12 | c.1470C>T p.I490= | Silent (SNP) | VAF 22/214 reads (10%) | called by muse, varscan2
- SPTBN2 | c.5901C>T p.I1967= | Silent (SNP) | VAF 130/574 reads (23%) | catalogued as rs200009167; called by muse, mutect2, varscan2
- ZNF300 | c.1254C>T p.F418= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- A2M | c.-15C>A | 5'UTR (SNP) | VAF 88/358 reads (25%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848459 T>A | 5'Flank (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- HROB | c.*13G>A | 3'UTR (SNP) | VAF 12/119 reads (10%) | catalogued as rs776450660; called by muse, mutect2, varscan2
- MTX1 | chr1:155215119 G>A | 3'Flank (SNP) | VAF 70/640 reads (11%) | called by muse, mutect2, varscan2
- PRRX1 | c.599+3899G>T | Intron (SNP) | VAF 21/269 reads (8%) | called by muse, mutect2
